Surgical pathology report (de-identified scan), TCGA case TCGA-DB-5280, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-5280-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

Brain, right frontal lobe, excision: Grade 2 (of 4) oligoastrocytoma, astrocytic predominant (WHO, grade II). See comment.

Comment: The presence of areas of high cellularity and the cellular pleomorphism are worrisome features for early anaplastic transformation, however, proliferative activity is still low (mitotic index up to 2-3 mitoses per 10 HPF). No endothelial vascular changes or necrosis are seen.

Immunohistochemical stains were performed on paraffin embedded tissue using antibodies to GFAP, p53 and MIB-1. GFAP is focally positive in tumor cells. p53 protein is positive in tumor cells. MIB-1 labeling varies from low to moderate (up to 4-6%). The findings support the above diagnosis.

FISH studies for 1p19q deletion will be performed and reported as an addendum.

TCGA-DB-5280

ADDENDA:

1p and 19q FISH studies were performed on cells within paraffin sections from tumor. Two hybridizations were performed: one with a 19q probe/control 19p pair and one with a 1p probe/control 1q pair. The 19q and 1p probes mapped to the regions that are commonly deleted in gliomas. The 19q to 19p probe ratio was 0.98. The 1p to 1q probe ratio was 0.98. For both probes, the normal ratio is approximately 1. Any ratio less than 0.80 is consistent with deletion of the chromosomal region of interest.

[page 2 of 2]
There was no evidence of deletion of 1p or 19q. The results are consistent with a tetraploid tumor karyotype or additional copies of chromosomes 1 and 19. Similar results have been observed in other glioma specimens.

This test was developed and its performance characteristics determined by Laboratory Medicine and Pathology, [REDACTED] has not been cleared or approved by the U.S. Food and Drug Administration, and is to be used as an adjunct to existing clinical and pathological information. This test does not rule out other chromosome anomalies.

[REDACTED]

[REDACTED]

Preliminary Frozen Section Consultation:

Brain, right frontal lobe, excision: Glioma. Hold for grading.

Gross Description:

Tissue from right frontal lobe brain (3.8 x 3.7 x 2.2 cm).

Block Summary:

Part A: right frontal tumor

- 1 Rt Frontal Tx
- 2 Rt Frontal Tx
- 3 Rt Frontal Tx
- 4 Rt Frontal Tx
- 5 Rt Frontal Tx
- 6 Rt Frontal Tx
- 7 Frontal Tx
- 8 Rt Frontal Tx
- 9 Rt Frontal Tx
- 10 Rt Frontal Tx
- 11 Rt Frontal Tx
- 12 Rt Frontal Tx
- 13 Rt Frontal Tx
- 14 Rt Frontal Tx
- 15 Rt Frontal Tx
- [REDACTED]

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file 06a30256-a279-4dd4-b8ae-37156d09e3c6 (TCGA-DB-5280.9592281F-2FAE-4376-9F64-EF19027CB4C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).